Somatic mutation profile of tumor specimen TCGA-13-0920-01A (aliquot TCGA-13-0920-01A-01W-0421-09) from TCGA case TCGA-13-0920, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 65.9 years (24,064 days).
Specimen TCGA-13-0920-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) db03beea-2a3b-4b21-aaec-012b1993029f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-0920-10A (Blood Derived Normal), aliquot TCGA-13-0920-10A-01W-0420-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7d3ee0fd-9630-4026-a9f9-510c35bfa77d

The open-access MAF lists 296 somatic variants for this specimen: 227 protein-altering or splice-affecting, 63 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 190, Silent 63, Frame Shift Del 12, Nonsense Mutation 11, Splice Site 8, In Frame Del 4, RNA 4, Frame Shift Ins 1, 3'UTR 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.298C>T p.Q100* | Nonsense Mutation (SNP) | VAF 220/271 reads (81%) | catalogued as rs1567555994, CM156961, COSV52702138, COSV53867973; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.3558G>T p.W1186C | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100229169; called by muse, mutect2
- ABCA13 | c.4549T>A p.S1517T | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.697); catalogued as COSV70025702; called by muse, mutect2, varscan2
- ABCA13 | c.10711T>A p.F3571I | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs992478979, COSV101446954, COSV101447046; called by muse, mutect2
- ABCC10 | c.4183G>T p.A1395S (on ENST00000372530 / NM_001198934.2; = p.A1367S on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55084272; called by muse, mutect2, varscan2
- ABCC9 | c.1682C>A p.A561D | Missense Mutation (SNP) | VAF 13/181 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV99686305; called by muse, mutect2
- ACP6 | c.238C>G p.L80V | Missense Mutation (SNP) | VAF 10/141 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100984234; called by muse, mutect2
- ADAM19 | c.2050C>T p.P684S | Missense Mutation (SNP) | VAF 6/7 reads (86%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV57422572, COSV57441331; called by mutect2, varscan2
- ADGRE3 | c.1920+1G>T p.X640_splice | Splice Site (SNP) | VAF 12/238 reads (5%) | catalogued as COSV99506439; called by muse, mutect2
- ADPRM | c.84T>G p.F28L | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV101126080; called by muse, mutect2
- AHNAK | c.16762T>G p.L5588V | Missense Mutation (SNP) | VAF 158/680 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV57203333; called by muse, mutect2, varscan2
- AKR1C1 | c.562T>G p.C188G | Missense Mutation (SNP) | VAF 26/500 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101080514, COSV101080581; called by muse, mutect2
- ALB | c.701C>A p.A234D | Missense Mutation (SNP) | VAF 46/381 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV55735709; called by muse, mutect2, varscan2
- ANKFY1 | c.2426T>G p.V809G (on ENST00000341657 / NM_001330063.2; = p.V810G on NM_016376.5) | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as rs1299441630, COSV100492894; called by muse, mutect2
- ANKRD29 | c.379G>A p.V127M | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs1204906985, COSV99409239; called by muse, mutect2, varscan2
- APOB | c.11806A>T p.I3936F | Missense Mutation (SNP) | VAF 8/131 reads (6%) | SIFT tolerated (0.48); PolyPhen benign (0.022); catalogued as COSV99266598; called by muse, mutect2
- AREG | c.334dup p.Q112Pfs*7 | Frame Shift Ins (INS) | VAF 24/190 reads (13%) | catalogued as rs757742243; called by mutect2, varscan2
- ARHGEF19 | c.2363A>C p.K788T | Missense Mutation (SNP) | VAF 51/168 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.179); catalogued as COSV54615004; called by muse, mutect2, varscan2
- ARMC10 | c.811C>T p.H271Y | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.558); catalogued as rs754574306, COSV58521124; called by muse, mutect2, varscan2
- ARSJ | c.391A>G p.T131A | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV100192876; called by muse, mutect2, varscan2
- ASTL | c.676A>C p.M226L | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.73); PolyPhen benign (0.114); catalogued as COSV100668402; called by muse, mutect2
- ATAT1 | c.742G>C p.E248Q | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.584); catalogued as COSV53312535; called by muse, mutect2, varscan2
- BEND2 | c.826G>C p.V276L | Missense Mutation (SNP) | VAF 62/239 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as COSV101192113; called by muse, mutect2, varscan2
- BEND2 | c.145G>A p.V49I | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); catalogued as COSV66214992; called by muse, mutect2, varscan2
- BNC2 | c.1145C>G p.P382R | Missense Mutation (SNP) | VAF 42/183 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.104); catalogued as rs761522806, COSV66140586; called by muse, mutect2, varscan2
- C5 | c.2204C>T p.A735V | Missense Mutation (SNP) | VAF 17/238 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.688); catalogued as COSV99798285; called by muse, mutect2
- CACHD1 | c.1165A>T p.T389S | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.428); catalogued as COSV99262734; called by muse, mutect2, varscan2
- CASS4 | c.760A>T p.S254C | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV64385367; called by muse, mutect2, varscan2
- CCDC40 | c.2330G>T p.W777L | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100884281; called by muse, mutect2
- CCL21 | c.98T>C p.L33P | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99425626; called by muse, mutect2
- CCN3 | c.864G>C p.K288N | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV52383019; called by muse, mutect2, varscan2
- CDC23 | c.1364G>A p.C455Y | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV101203133; called by muse, mutect2
- CDH8 | c.43C>A p.P15T | Missense Mutation (SNP) | VAF 43/213 reads (20%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.079); catalogued as COSV54847529; called by muse, mutect2, varscan2
- CDKAL1 | c.661T>A p.C221S | Missense Mutation (SNP) | VAF 21/165 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51179685; called by muse, mutect2, varscan2
- CFAP100 | c.47A>T p.D16V | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.039); catalogued as COSV100729322; called by muse, mutect2, varscan2
- CFAP94 | c.1333G>T p.V445L (on ENST00000320267 / NM_001352064.2; = p.V451L on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV57230816; called by muse, mutect2, varscan2
- CGN | c.3409G>A p.E1137K | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54967840; called by muse, mutect2, varscan2
- CHRNA2 | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 40/61 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs142375828; called by muse, mutect2, varscan2
- CLOCK | c.1706A>T p.Q569L | Missense Mutation (SNP) | VAF 29/216 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.245); catalogued as COSV59400373; called by muse, mutect2, varscan2
- CLVS1 | c.857C>T p.T286M | Missense Mutation (SNP) | VAF 33/328 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.125); catalogued as rs148453129, COSV57972301; called by muse, mutect2, varscan2
- CNGA3 | c.1775C>A p.P592H | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99735981, COSV99736913; called by muse, mutect2, varscan2
- CNNM4 | c.716G>T p.G239V | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65660200; called by muse, mutect2, varscan2
- CNTROB | c.2074G>T p.D692Y | Missense Mutation (SNP) | VAF 23/747 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.495); catalogued as COSV100972718; called by muse, mutect2
- COL4A6 | c.1450T>A p.C484S | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100564528; called by muse, mutect2, varscan2
- COPS7A | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 23/238 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99976403; called by muse, mutect2, varscan2
- CSPP1 | c.985G>T p.D329Y (on ENST00000676605; = p.D288Y on NM_024790.6) | Missense Mutation (SNP) | VAF 30/192 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as COSV51580050; called by muse, mutect2, varscan2
- CTAGE1 | c.1490C>A p.S497* | Nonsense Mutation (SNP) | VAF 19/491 reads (4%) | catalogued as COSV101194607; called by muse, mutect2
- CYP1A1 | c.1519C>A p.Q507K | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV65696560; called by muse, mutect2, varscan2
- CYP2A13 | c.164A>G p.Y55C | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.028); catalogued as COSV57837714; called by muse, mutect2, varscan2
- DCAF8L1 | c.1186G>A p.V396I | Missense Mutation (SNP) | VAF 49/263 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs754870602, COSV71595106; called by muse, mutect2, varscan2
- DHX32 | c.1882-1G>C p.X628_splice | Splice Site (SNP) | VAF 114/275 reads (41%) | catalogued as COSV52938083; called by muse, mutect2, varscan2
- DIPK2B | c.1186G>T p.D396Y | Missense Mutation (SNP) | VAF 12/129 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); catalogued as COSV101211690; called by muse, mutect2, varscan2
- DLAT | c.560C>G p.P187R | Missense Mutation (SNP) | VAF 106/210 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV54768978; called by muse, mutect2, varscan2
- DNAH2 | c.2497G>A p.E833K | Missense Mutation (SNP) | VAF 38/351 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.838); catalogued as COSV66716117, COSV66717543, COSV66720257; called by muse, mutect2, varscan2
- DNAH5 | c.3052A>T p.I1018F | Missense Mutation (SNP) | VAF 7/129 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as COSV54242688; called by muse, mutect2
- DNAJB7 | c.330C>G p.H110Q | Missense Mutation (SNP) | VAF 29/180 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV53420719, COSV53420815; called by muse, mutect2, varscan2
- DNAJC16 | c.1608G>C p.M536I | Missense Mutation (SNP) | VAF 94/1214 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.03); catalogued as COSV65449377; called by muse, mutect2
- DOCK7 | c.1702C>A p.P568T | Missense Mutation (SNP) | VAF 38/196 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99225132; called by muse, mutect2, varscan2
- DSG1 | c.869T>A p.I290N | Missense Mutation (SNP) | VAF 132/298 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV57133109; called by muse, mutect2, varscan2
- DZIP3 | c.33-2A>G p.X11_splice | Splice Site (SNP) | VAF 20/382 reads (5%) | catalogued as COSV100847920; called by muse, mutect2
- EFCAB7 | c.1174A>T p.R392* | Nonsense Mutation (SNP) | VAF 16/243 reads (7%) | catalogued as COSV100937712; called by muse, mutect2
- EIF4A3 | c.1129G>C p.A377P | Missense Mutation (SNP) | VAF 53/434 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV53919542; called by muse, mutect2, varscan2
- EML4 | c.2344G>C p.V782L | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); catalogued as COSV59292545; called by muse, mutect2
- EXOC4 | c.17C>A p.A6D | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.981); catalogued as COSV54083179; called by muse, mutect2, varscan2
- F5 | c.6586A>T p.I2196F | Missense Mutation (SNP) | VAF 104/352 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63120258; called by mutect2, varscan2
- F5 | c.1180G>T p.V394F | Missense Mutation (SNP) | VAF 26/349 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100889176; called by muse, mutect2
- FLG2 | c.2386C>A p.Q796K | Missense Mutation (SNP) | VAF 221/718 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.118); catalogued as COSV66166546; called by muse, mutect2, varscan2
- FSCB | c.1813G>A p.E605K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.435); catalogued as rs866097790, COSV100469559; called by muse, varscan2
- FTO | c.737G>T p.S246I | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV101150673; called by muse, mutect2, varscan2
- G6PC | c.910G>A p.V304I | Missense Mutation (SNP) | VAF 84/340 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs768385469, COSV53830027; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GEMIN5 | c.1252G>T p.V418L | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV99594124; called by muse, mutect2, varscan2
- HCFC2 | c.1373C>T p.T458M | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs574023442, COSV57557888, COSV57559881; called by muse, mutect2, varscan2
- HECW2 | c.1561C>A p.H521N | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as COSV53679555; called by muse, mutect2
- HTN3 | c.37A>T p.M13L | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV66879359; called by muse, mutect2, varscan2
- HTR2C | c.163T>A p.W55R | Missense Mutation (SNP) | VAF 64/206 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52201219, COSV52218410; called by muse, mutect2, varscan2
- HTR4 | c.1097G>C p.S366T | Missense Mutation (SNP) | VAF 46/284 reads (16%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV100088839; called by muse, mutect2, varscan2
- HTT | c.4375C>G p.R1459G | Missense Mutation (SNP) | VAF 32/156 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100750992; called by muse, mutect2, varscan2
- IGHG2 | c.315G>C p.E105D | Missense Mutation (SNP) | VAF 200/372 reads (54%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs749303415; called by muse, mutect2, varscan2
- INTS2 | c.2993G>T p.C998F | Missense Mutation (SNP) | VAF 76/524 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.466); catalogued as COSV52150831; called by muse, mutect2, varscan2
- IRF8 | c.443A>G p.K148R | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.14); PolyPhen benign (0.074); catalogued as COSV51896616; called by muse, mutect2, varscan2
- ITGA5 | c.2307C>G p.S769R | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53215434; called by muse, varscan2
- KDM7A | c.2695T>G p.S899A | Missense Mutation (SNP) | VAF 9/137 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV99134768; called by muse, mutect2
- KLHDC1 | c.976G>C p.D326H | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); catalogued as COSV100833582; called by muse, mutect2
- KRBA2 | c.405C>G p.Y135* | Nonsense Mutation (SNP) | VAF 15/339 reads (4%) | catalogued as COSV100497696; called by muse, mutect2
- L3HYPDH | c.619G>C p.A207P | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV55966491; called by muse, mutect2, varscan2
- LAMC2 | c.1044C>G p.I348M | Missense Mutation (SNP) | VAF 14/322 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99917656; called by muse, mutect2
- LMBR1 | c.908T>C p.I303T | Missense Mutation (SNP) | VAF 27/552 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV100626747; called by muse, mutect2
- LRP2 | c.10555T>G p.C3519G | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55540323; called by muse, mutect2, varscan2
- LRP2 | c.5749A>T p.N1917Y | Missense Mutation (SNP) | VAF 34/321 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99789420; called by muse, mutect2, varscan2
- LRP6 | c.4838C>A p.S1613Y | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV53783127, COSV53788777; called by muse, mutect2, varscan2
- LUZP4 | c.281A>T p.Q94L | Missense Mutation (SNP) | VAF 22/227 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV64218370; called by muse, mutect2
- MAP2 | c.2653G>T p.D885Y | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99560871; called by muse, mutect2
- MAP3K6 | c.2372T>G p.F791C | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100709311; called by muse, mutect2, varscan2
- MARS2 | c.1621G>A p.V541I | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.251); catalogued as rs1387554348, COSV99986631; called by muse, mutect2
- MATR3 | c.719C>G p.S240W | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV63075711; called by muse, mutect2, varscan2
- MEPE | c.1043A>T p.K348M | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV100734973; called by muse, mutect2
- MTOR | c.231C>G p.S77R | Missense Mutation (SNP) | VAF 37/169 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as COSV100816461; called by muse, mutect2, varscan2
- MTTP | c.2659G>C p.D887H | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.371); catalogued as COSV99645384; called by muse, mutect2
- MTUS2 | c.1585G>T p.V529F | Missense Mutation (SNP) | VAF 26/303 reads (9%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as COSV101462300; called by muse, mutect2
- MUC17 | c.4561G>T p.V1521F | Missense Mutation (SNP) | VAF 41/423 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as COSV100074208; called by muse, mutect2
- MYCT1 | c.203T>A p.L68H | Missense Mutation (SNP) | VAF 134/277 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs1485814836, COSV65890769; called by muse, mutect2, varscan2
- MYH1 | c.2824G>T p.A942S | Missense Mutation (SNP) | VAF 39/528 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.082); catalogued as COSV99876386; called by muse, mutect2
- MYH11 | c.4636A>G p.T1546A | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.044); catalogued as COSV55545414; called by muse, mutect2
- MYH2 | c.940C>A p.P314T | Missense Mutation (SNP) | VAF 25/199 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as COSV55432133, COSV55434290, COSV99820512; called by muse, mutect2, varscan2
- MYH3 | c.446A>T p.Q149L | Missense Mutation (SNP) | VAF 28/473 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV99878210; called by muse, mutect2
- MYH4 | c.2445C>G p.I815M | Missense Mutation (SNP) | VAF 65/335 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV99701698; called by muse, mutect2, varscan2
- MYH7 | c.4076G>A p.R1359H | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs750836033, COSV62516140; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NAB2 | c.695G>A p.G232D | Missense Mutation (SNP) | VAF 21/30 reads (70%) | SIFT tolerated (0.66); PolyPhen benign (0.033); catalogued as COSV55665407; called by muse, mutect2, varscan2
- NET1 | c.290G>C p.R97P (on ENST00000355029 / NM_001047160.3; = p.R43P on NM_005863.5) | Missense Mutation (SNP) | VAF 25/284 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100742332; called by muse, mutect2
- NFE2L3 | c.895G>T p.A299S | Missense Mutation (SNP) | VAF 134/261 reads (51%) | SIFT tolerated (0.64); PolyPhen benign (0.006); catalogued as COSV50226199; called by muse, mutect2, varscan2
- NMUR1 | c.182T>G p.M61R | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV100532042; called by muse, mutect2, varscan2
- NR1H4 | c.477T>A p.G159= (on ENST00000551379 / NM_001206993.2; = p.G149= on NM_005123.4) | Splice Region (SNP) | VAF 6/82 reads (7%) | catalogued as COSV51856521, COSV99500851; called by muse, mutect2
- NUP210L | c.2065T>A p.F689I | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55142365; called by muse, mutect2
- OR1E1 | c.134T>A p.I45N | Missense Mutation (SNP) | VAF 72/501 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100491973; called by muse, mutect2, varscan2
- OR1E2 | c.805T>A p.L269I | Missense Mutation (SNP) | VAF 101/374 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.189); catalogued as COSV99943467, COSV99943509; called by muse, mutect2, varscan2
- OR2F2 | c.415G>A p.G139R | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.133); catalogued as rs1175463741, COSV101283832, COSV68832872; called by muse, mutect2, varscan2
- OR2J3 | c.204C>A p.N68K | Missense Mutation (SNP) | VAF 141/646 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.104); catalogued as rs201161327, COSV101013642; called by muse, mutect2, varscan2
- OR5D16 | c.491C>A p.S164Y | Missense Mutation (SNP) | VAF 26/279 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.211); catalogued as rs1368285050, COSV101004057; called by muse, mutect2
- OR5T3 | c.279G>T p.M93I | Missense Mutation (SNP) | VAF 24/436 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as COSV57381882; called by muse, mutect2
- OTOP3 | c.208C>T p.Q70* | Nonsense Mutation (SNP) | VAF 4/44 reads (9%) | catalogued as COSV100172928; called by muse, mutect2
- PALB2 | c.1547G>T p.R516I | Missense Mutation (SNP) | VAF 46/189 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99848731; called by muse, mutect2, varscan2
- PAXBP1 | c.597G>C p.K199N | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.351); catalogued as COSV99269374; called by muse, mutect2, varscan2
- PDE1B | c.30G>C p.E10D | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV99672773; called by muse, mutect2, varscan2
- PGAP3 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV99510679; called by muse, mutect2, varscan2
- PIK3CG | c.2706T>G p.F902L | Missense Mutation (SNP) | VAF 40/576 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.17); catalogued as COSV100783018; called by muse, mutect2
- PIP5K1A | c.625C>G p.P209A (on ENST00000368888 / NM_001135638.2; = p.P196A on NM_003557.3) | Missense Mutation (SNP) | VAF 37/307 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as COSV62957332, COSV62957893; called by muse, mutect2, varscan2
- PRKCB | c.542A>C p.K181T | Missense Mutation (SNP) | VAF 26/554 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.371); catalogued as COSV100334595; called by muse, mutect2
- PRPH2 | c.625G>A p.V209I | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs753657349, CD972426, CM101591, COSV57836140; called by muse, mutect2, varscan2
- PRPS1L1 | c.172A>G p.S58G | Missense Mutation (SNP) | VAF 113/856 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV72649790; called by muse, mutect2, varscan2
- PTPN13 | c.7103T>C p.I2368T (on ENST00000411767 / NM_080683.3; = p.I2349T on NM_006264.3) | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV57402230; called by muse, mutect2, varscan2
- PTPRG | c.2566C>A p.Q856K | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV55628232; called by muse, mutect2, varscan2
- RAB3B | c.473G>A p.G158E | Missense Mutation (SNP) | VAF 49/256 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100862520; called by muse, mutect2, varscan2
- RBM43 | c.538T>C p.F180L | Missense Mutation (SNP) | VAF 61/785 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as COSV100508603; called by muse, mutect2
- RGS12 | c.1517C>G p.S506C | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.613); catalogued as COSV60902068; called by muse, mutect2, varscan2
- RNF113A | c.760G>C p.D254H | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV101007078; called by muse, mutect2, varscan2
- RNF216 | c.532T>G p.F178V (on ENST00000425013 / NM_207116.3; = p.F235V on NM_207111.4) | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.053); catalogued as COSV66288961; called by muse, mutect2, varscan2
- RTP3 | c.530C>A p.P177Q | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV56123529; called by muse, mutect2, varscan2
- RUFY1 | c.1366C>G p.L456V | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.224); catalogued as COSV60158280; called by muse, mutect2, varscan2
- RUSF1 | c.785G>A p.G262E | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.026); catalogued as COSV57890041; called by muse, mutect2, varscan2
- RYR1 | c.12465T>G p.H4155Q | Missense Mutation (SNP) | VAF 34/218 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.368); catalogued as COSV100616276; called by muse, mutect2, varscan2
- RYR2 | c.6365C>T p.S2122F | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.744); catalogued as COSV63707012; called by muse, mutect2
- SCD5 | c.291G>A p.W97* | Nonsense Mutation (SNP) | VAF 25/60 reads (42%) | catalogued as COSV51101850; called by muse, mutect2, varscan2
- SCN7A | c.4985C>T p.A1662V | Missense Mutation (SNP) | VAF 59/595 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as rs369467319; called by muse, mutect2
- SERPINA4 | c.171C>A p.D57E | Missense Mutation (SNP) | VAF 23/297 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.331); catalogued as rs1160359144, COSV100097320; called by muse, mutect2
- SERPINB12 | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 53/674 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99501744; called by muse, mutect2
- SERPINE1 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 90/856 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.755); catalogued as rs143027028; called by muse, mutect2, varscan2
- SEZ6L2 | c.142T>A p.S48T | Missense Mutation (SNP) | VAF 39/54 reads (72%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV58097082; called by muse, mutect2, varscan2
- SF3A1 | c.304A>T p.K102* | Nonsense Mutation (SNP) | VAF 14/85 reads (16%) | catalogued as COSV53167139; called by muse, mutect2, varscan2
- SKA3 | c.995T>A p.L332* | Nonsense Mutation (SNP) | VAF 22/252 reads (9%) | catalogued as COSV100006430; called by muse, varscan2
- SLC2A4 | c.34G>A p.D12N | Missense Mutation (SNP) | VAF 21/239 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as rs562894482, COSV100435289, COSV100435302; called by muse, mutect2
- SLC44A4 | c.905A>G p.Y302C | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57665725; called by muse, mutect2, varscan2
- SMAP2 | c.692C>A p.S231Y | Missense Mutation (SNP) | VAF 36/782 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.353); catalogued as COSV101019151; called by muse, mutect2
- SNAPC4 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1033035621; called by muse, mutect2, varscan2
- SORL1 | c.3127C>T p.P1043S | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.042); catalogued as rs1406795213; called by muse, mutect2, varscan2
- ST6GALNAC1 | c.1603C>A p.Q535K | Missense Mutation (SNP) | VAF 6/58 reads (10%) | PolyPhen benign (0.026); catalogued as rs1314291992; called by muse, mutect2
- SYN3 | c.366G>T p.E122D | Missense Mutation (SNP) | VAF 114/1696 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV60503400; called by muse, mutect2
- SYTL2 | c.1255G>C p.G419R | Missense Mutation (SNP) | VAF 175/455 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV100313827, COSV100314544; called by muse, mutect2, varscan2
- SYTL4 | c.1101G>C p.E367D | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52165292; called by muse, mutect2, varscan2
- TACC2 | c.1223C>T p.S408F | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV57745822; called by muse, mutect2, varscan2
- TADA1 | c.451C>G p.L151V | Missense Mutation (SNP) | VAF 143/387 reads (37%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.806); catalogued as COSV63309816; called by muse, mutect2, varscan2
- TBC1D8B | c.1373A>T p.E458V | Missense Mutation (SNP) | VAF 11/126 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.938); catalogued as COSV99344686; called by muse, mutect2
- TBK1 | c.543C>G p.H181Q | Missense Mutation (SNP) | VAF 16/179 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100538254; called by muse, mutect2
- TDP2 | c.207C>A p.S69R | Missense Mutation (SNP) | VAF 105/152 reads (69%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV57763418; called by muse, mutect2, varscan2
- TFAP2D | c.1240A>T p.T414S | Missense Mutation (SNP) | VAF 30/265 reads (11%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as COSV50408236; called by muse, mutect2, varscan2
- TG | c.3896A>T p.Q1299L | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99601952; called by muse, mutect2, varscan2
- TKTL1 | c.548A>T p.N183I | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV99474050; called by muse, mutect2, varscan2
- TLE4 | c.1618A>T p.R540* | Nonsense Mutation (SNP) | VAF 17/67 reads (25%) | catalogued as COSV99512578; called by muse, mutect2, varscan2
- TLN1 | c.4632G>C p.K1544N | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100147952; called by muse, mutect2, varscan2
- TMTC2 | c.122C>G p.T41S | Missense Mutation (SNP) | VAF 48/285 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.573); catalogued as COSV100338415; called by muse, mutect2, varscan2
- TNC | c.4312G>C p.E1438Q | Missense Mutation (SNP) | VAF 22/570 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.097); catalogued as COSV100406015; called by muse, mutect2
- TOX4 | c.1642G>A p.V548I | Missense Mutation (SNP) | VAF 36/338 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV52967850, COSV99398435; called by muse, mutect2
- TPMT | c.326A>G p.E109G | Missense Mutation (SNP) | VAF 22/261 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100015467; called by muse, mutect2
- TRIM39 | c.1306G>A p.G436R | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.679); catalogued as COSV64954892; called by muse, mutect2, varscan2
- TRMT44 | c.1310G>T p.R437M | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV67663319; called by muse, mutect2, varscan2
- TSGA13 | c.430C>T p.P144S | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.928); catalogued as COSV100449686; called by muse, mutect2
- TTC4 | c.777G>C p.E259D | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV100988444; called by muse, mutect2
- TTN | c.51218C>T p.P17073L (on ENST00000591111; = p.P9649L on NM_003319.4) | Missense Mutation (SNP) | VAF 169/325 reads (52%) | PolyPhen probably damaging (0.999); catalogued as COSV59878825; called by muse, mutect2, varscan2
- UBAP2 | c.1030G>A p.V344I | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.099); catalogued as rs780923321, COSV62545098; called by muse, mutect2, varscan2
- USH2A | c.10077T>A p.C3359* | Nonsense Mutation (SNP) | VAF 74/352 reads (21%) | catalogued as COSV56326091; called by muse, mutect2, varscan2
- USP49 | c.152A>G p.E51G | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV99790422; called by muse, varscan2
- VEPH1 | c.2323G>C p.V775L | Missense Mutation (SNP) | VAF 17/197 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.372); catalogued as COSV100747758; called by muse, mutect2
- VPS13D | c.11485G>C p.V3829L | Missense Mutation (SNP) | VAF 28/592 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as COSV99167511; called by muse, mutect2
- WDR62 | c.333-1G>C p.X111_splice | Splice Site (SNP) | VAF 16/382 reads (4%) | catalogued as COSV99543895; called by muse, mutect2
- WFDC12 | c.61G>A p.V21M | Missense Mutation (SNP) | VAF 18/236 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.037); catalogued as COSV100859099; called by muse, mutect2
- YTHDF1 | c.598G>A p.V200I | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.46); catalogued as rs374927858; called by muse, mutect2, varscan2
- ZBTB49 | c.871G>C p.D291H | Missense Mutation (SNP) | VAF 28/233 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); catalogued as COSV61924238; called by muse, mutect2, varscan2
- ZFAND2B | c.395A>G p.H132R | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99202458; called by muse, mutect2, varscan2
- ZKSCAN1 | c.769C>G p.Q257E | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.682); catalogued as COSV60872961; called by muse, mutect2, varscan2
- ZNF318 | c.2251A>G p.R751G | Missense Mutation (SNP) | VAF 34/444 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100546358; called by muse, mutect2
- ZNF346 | c.780del p.F261Sfs*48 | Frame Shift Del (DEL) | VAF 143/578 reads (25%) | catalogued as COSV56155580; called by mutect2, pindel, varscan2
- ZNF711 | c.1729C>A p.L577I | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV52151264; called by muse, mutect2, varscan2
- AHSA1 | c.302del p.G101Dfs*21 | Frame Shift Del (DEL) | VAF 7/84 reads (8%) | called by mutect2, pindel
- ARHGEF35 | c.1255T>C p.C419R | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ARMCX2 | c.1046_1047del p.E349Vfs*6 | Frame Shift Del (DEL) | VAF 12/104 reads (12%) | called by pindel, varscan2
- CDC42BPA | c.1558A>G p.R520G | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.027); called by muse, mutect2
- CFH | c.2204A>T p.H735L | Missense Mutation (SNP) | VAF 10/277 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.173); called by muse, mutect2
- CLRN2 | c.668_673del p.A223_T224del | In Frame Del (DEL) | VAF 55/264 reads (21%) | called by mutect2, pindel, varscan2
- CNKSR3 | c.1176_1181del p.S392_R393del | In Frame Del (DEL) | VAF 78/315 reads (25%) | called by mutect2, pindel, varscan2
- EML4 | c.2534_2539del p.N845_D846del | In Frame Del (DEL) | VAF 24/288 reads (8%) | called by mutect2, pindel
- EXOSC2 | c.215T>A p.L72* | Nonsense Mutation (SNP) | VAF 6/120 reads (5%) | called by muse, mutect2
- FAM166A | c.191T>C p.F64S | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.429); called by muse, mutect2
- FAT3 | c.11091C>A p.N3697K | Missense Mutation (SNP) | VAF 4/92 reads (4%) | SIFT tolerated (0.42); PolyPhen benign (0.046); called by muse, mutect2
- FCGBP | c.1760T>A p.V587D | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FRG2B | c.329_331+4del p.X110_splice | Splice Site (DEL) | VAF 42/136 reads (31%) | called by mutect2, pindel, varscan2
- IGSF10 | c.6941_6963del p.V2314Efs*19 | Frame Shift Del (DEL) | VAF 64/657 reads (10%) | called by mutect2, pindel
- KCNA1 | c.460_496del p.W154Pfs*27 | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | called by mutect2, pindel
- KIAA1755 | c.895G>T p.G299W | Missense Mutation (SNP) | VAF 12/352 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2
- KIR2DL4 | c.395G>C p.G132A (on ENST00000396284; = p.G93A on NM_001080770.2) | Missense Mutation (SNP) | VAF 64/594 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, varscan2
- LGALS13 | c.217A>G p.M73V | Missense Mutation (SNP) | VAF 10/187 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2
- LMBRD2 | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.012); called by muse, mutect2
- MLIP | c.863C>A p.P288Q | Missense Mutation (SNP) | VAF 8/196 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.063); called by muse, mutect2
- MROH2B | c.604_610delinsCTT p.S202Lfs*5 | Frame Shift Del (DEL) | VAF 29/211 reads (14%) | called by pindel, varscan2*
- MYT1L | c.1866_1913del p.N622_E637del | In Frame Del (DEL) | VAF 14/116 reads (12%) | called by mutect2, pindel
- NISCH | c.1122C>A p.H374Q | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- OR5D16 | c.929A>T p.K310I | Missense Mutation (SNP) | VAF 7/147 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.354); called by muse, mutect2
- OR5L2 | c.467_469delinsTT p.S156Ffs*2 | Frame Shift Del (DEL) | VAF 91/731 reads (12%) | called by pindel, varscan2*
- PGM2 | c.229_242del p.T77Yfs*14 | Frame Shift Del (DEL) | VAF 10/66 reads (15%) | called by mutect2, pindel
- PKP2 | c.2314C>G p.P772A | Missense Mutation (SNP) | VAF 9/215 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.538); called by muse, mutect2
- PLEK | c.488_491del p.D163Gfs*16 | Frame Shift Del (DEL) | VAF 24/178 reads (13%) | called by pindel, varscan2
- RINT1 | c.754_760del p.V252* | Frame Shift Del (DEL) | VAF 67/458 reads (15%) | called by pindel, varscan2
- SLC4A1AP | c.1346-27_1353del p.X449_splice | Splice Site (DEL) | VAF 16/174 reads (9%) | called by mutect2, pindel
- SLC9A8 | c.570-11_577del p.X190_splice | Splice Site (DEL) | VAF 39/237 reads (16%) | called by mutect2, pindel, varscan2
- SPTAN1 | c.2865del p.C956Afs*33 | Frame Shift Del (DEL) | VAF 50/108 reads (46%) | called by mutect2, pindel, varscan2
- TRIO | c.8206_8210+12del p.X2736_splice | Splice Site (DEL) | VAF 28/79 reads (35%) | called by mutect2, pindel
- UHRF1BP1L | c.2683C>A p.P895T | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.01); called by muse, mutect2
- WDR46 | c.1824del p.F608Lfs*? | Frame Shift Del (DEL) | VAF 22/64 reads (34%) | called by mutect2, pindel, varscan2
- ZNF697 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.017); called by muse, varscan2
- ACTBL2 | c.927C>T p.G309= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as COSV101379385; called by muse, mutect2, varscan2
- ADH1A | c.252C>T p.V84= | Silent (SNP) | VAF 35/235 reads (15%) | catalogued as COSV52924253; called by muse, mutect2, varscan2
- ANAPC4 | c.1896A>G p.R632= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as rs779121653, COSV59542879; called by muse, mutect2, varscan2
- AQP10 | c.381G>A p.Q127= | Silent (SNP) | VAF 44/178 reads (25%) | catalogued as rs753161641, COSV100270349; called by muse, varscan2
- BRD9 | c.1551T>G p.P517= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as COSV100057350; called by muse, mutect2
- CD3E | c.201C>T p.G67= | Silent (SNP) | VAF 44/619 reads (7%) | catalogued as rs188934551; called by muse, mutect2
- CLPTM1 | c.90C>T p.S30= | Silent (SNP) | VAF 4/43 reads (9%) | catalogued as rs972269167, COSV100493869; called by muse, mutect2, varscan2
- CR1 | c.2673C>A p.P891= | Silent (SNP) | VAF 81/266 reads (30%) | catalogued as COSV65455704, COSV65456410; called by muse, mutect2, varscan2
- DDR2 | c.117C>T p.G39= | Silent (SNP) | VAF 76/165 reads (46%) | catalogued as COSV63369196; called by muse, mutect2, varscan2
- DLL4 | c.663C>T p.I221= | Silent (SNP) | VAF 24/52 reads (46%) | catalogued as COSV99989903; called by muse, mutect2, varscan2
- DPPA4 | c.303C>A p.A101= | Silent (SNP) | VAF 76/507 reads (15%) | catalogued as COSV100169552; called by muse, mutect2, varscan2
- ENTHD1 | c.81C>T p.N27= | Silent (SNP) | VAF 126/447 reads (28%) | catalogued as rs146928757; called by muse, mutect2, varscan2
- EPHA5 | c.1830C>T p.C610= | Silent (SNP) | VAF 27/91 reads (30%) | catalogued as rs200675919, COSV56630556; called by muse, mutect2, varscan2
- FLRT2 | c.1827C>T p.I609= | Silent (SNP) | VAF 124/471 reads (26%) | catalogued as rs1355606166, COSV58136058; called by muse, mutect2, varscan2
- GAB4 | c.609G>A p.P203= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as rs545946229, COSV68753009; called by muse, mutect2, varscan2
- GBF1 | c.429G>C p.L143= | Silent (SNP) | VAF 46/139 reads (33%) | catalogued as COSV64142683; called by muse, mutect2, varscan2
- H2BC8 | c.117C>T p.S39= | Silent (SNP) | VAF 13/222 reads (6%) | catalogued as COSV55127474, COSV99773293; called by muse, mutect2
- HLA-DRA | c.423G>A p.V141= | Silent (SNP) | VAF 23/346 reads (7%) | catalogued as COSV100895087; called by muse, mutect2
- HMGCS2 | c.1260C>T p.F420= | Silent (SNP) | VAF 25/111 reads (23%) | catalogued as rs15609, COSV65567095; called by muse, mutect2, varscan2
- IKZF4 | c.1206C>T p.V402= | Silent (SNP) | VAF 28/209 reads (13%) | catalogued as COSV56267159; called by muse, mutect2, varscan2
- ITLN1 | c.537G>T p.L179= | Silent (SNP) | VAF 38/319 reads (12%) | catalogued as COSV58273794; called by muse, mutect2, varscan2
- KIF26B | c.4032T>A p.S1344= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV100832858; called by muse, mutect2, varscan2
- KLKB1 | c.1560C>A p.T520= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV52993811; called by muse, mutect2, varscan2
- LPA | c.5235T>A p.A1745= | Silent (SNP) | VAF 134/320 reads (42%) | catalogued as COSV100307427; called by muse, mutect2, varscan2
- MAPRE3 | c.24A>G p.T8= | Silent (SNP) | VAF 65/370 reads (18%) | catalogued as COSV51866232; called by muse, mutect2, varscan2
- MED12L | c.1812C>T p.C604= | Silent (SNP) | VAF 18/181 reads (10%) | catalogued as rs762849776, COSV99853855; called by muse, mutect2, varscan2
- MUC16 | c.42249C>T p.I14083= | Silent (SNP) | VAF 12/128 reads (9%) | catalogued as COSV101109849, COSV66689721; called by muse, mutect2
- NIM1K | c.1017G>C p.L339= | Silent (SNP) | VAF 30/247 reads (12%) | catalogued as COSV100390279; called by muse, mutect2, varscan2
- NRXN3 | c.60C>G p.S20= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as COSV73581695; called by muse, mutect2, varscan2
- OR10AG1 | c.582G>A p.A194= | Silent (SNP) | VAF 29/139 reads (21%) | catalogued as rs556408380, COSV56631333; called by muse, mutect2, varscan2
- OR10C1 | c.381C>T p.I127= (on ENST00000622521; = p.I125= on NM_013941.3) | Silent (SNP) | VAF 12/326 reads (4%) | catalogued as COSV101010859; called by muse, mutect2
- OR52A5 | c.534T>A p.S178= | Silent (SNP) | VAF 12/209 reads (6%) | catalogued as COSV100263499; called by muse, mutect2
- OR5I1 | c.177C>T p.T59= | Silent (SNP) | VAF 19/183 reads (10%) | catalogued as rs750061398, COSV56885342; called by muse, mutect2, varscan2
- OR5M3 | c.495C>T p.Y165= | Silent (SNP) | VAF 36/285 reads (13%) | called by muse, varscan2
- OR7A17 | c.846C>G p.T282= | Silent (SNP) | VAF 14/270 reads (5%) | catalogued as COSV59414581; called by muse, mutect2
- PASD1 | c.2034A>T p.S678= | Silent (SNP) | VAF 102/283 reads (36%) | catalogued as COSV64854033; called by muse, mutect2, varscan2
- PKHD1 | c.4170G>T p.R1390= | Silent (SNP) | VAF 181/383 reads (47%) | catalogued as COSV61859948, COSV61860734; called by muse, varscan2
- PLAGL2 | c.576C>T p.P192= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs750351410; called by muse, mutect2, varscan2
- POLK | c.735A>G p.E245= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as COSV99606201; called by muse, mutect2, varscan2
- PON3 | c.357C>T p.F119= | Silent (SNP) | VAF 11/289 reads (4%) | catalogued as COSV55699907; called by muse, mutect2
- PPP1R26 | c.3534G>A p.R1178= | Silent (SNP) | VAF 9/12 reads (75%) | catalogued as rs762131476, COSV100778114; called by muse, mutect2, varscan2
- PREPL | c.2124G>A p.E708= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as COSV99576306; called by muse, mutect2
- PTPN4 | c.117T>A p.T39= | Silent (SNP) | VAF 35/225 reads (16%) | catalogued as COSV55297209; called by muse, mutect2, varscan2
- RESF1 | c.3420C>T p.I1140= | Silent (SNP) | VAF 36/287 reads (13%) | catalogued as COSV100440447; called by muse, mutect2, varscan2
- RPS3A | c.525G>A p.E175= | Silent (SNP) | VAF 7/78 reads (9%) | catalogued as COSV56838949; called by muse, mutect2
- SCP2D1 | c.363C>A p.G121= | Silent (SNP) | VAF 18/165 reads (11%) | catalogued as COSV99601994, COSV99602136; called by muse, mutect2, varscan2
- SFTPD | c.768T>C p.N256= | Silent (SNP) | VAF 21/345 reads (6%) | catalogued as COSV100954546; called by muse, mutect2
- SLC35B2 | c.33G>A p.L11= | Silent (SNP) | VAF 27/200 reads (14%) | catalogued as COSV51487425; called by muse, mutect2, varscan2
- SLITRK3 | c.282C>A p.T94= | Silent (SNP) | VAF 45/377 reads (12%) | catalogued as COSV53845500; called by muse, mutect2, varscan2
- SP100 | c.2443T>C p.L815= | Silent (SNP) | VAF 48/156 reads (31%) | catalogued as COSV60841365; called by muse, mutect2, varscan2
- SYCP2 | c.3171A>G p.R1057= | Silent (SNP) | VAF 11/123 reads (9%) | catalogued as COSV100698351, COSV62765757; called by muse, mutect2
- TLR4 | c.1974G>T p.L658= (on ENST00000355622 / NM_138554.5; = p.L618= on NM_003266.4) | Silent (SNP) | VAF 8/124 reads (6%) | catalogued as COSV62923157; called by muse, mutect2
- TP53BP2 | c.1878A>G p.G626= (on ENST00000343537 / NM_001031685.3; = p.G497= on NM_005426.2) | Silent (SNP) | VAF 20/282 reads (7%) | catalogued as COSV100636708, COSV59066347; called by muse, mutect2
- TRABD2A | c.981C>G p.A327= (on ENST00000409520 / NM_001277053.2; = p.A278= on NM_001080824.3) | Silent (SNP) | VAF 28/361 reads (8%) | catalogued as COSV100120035; called by muse, mutect2
- TRBV28 | c.117T>C p.F39= | Silent (SNP) | VAF 33/147 reads (22%) | called by muse, mutect2, varscan2
- TTN | c.55923C>T p.D18641= (on ENST00000591111; = p.D11217= on NM_003319.4) | Silent (SNP) | VAF 28/341 reads (8%) | catalogued as COSV100620628; called by muse, mutect2
- UBE4B | c.3582G>C p.G1194= (on ENST00000343090 / NM_001105562.3; = p.G1065= on NM_006048.5) | Silent (SNP) | VAF 32/66 reads (48%) | catalogued as COSV53526997; called by muse, mutect2, varscan2
- WASHC2C | c.1584A>T p.S528= | Silent (SNP) | VAF 8/218 reads (4%) | catalogued as COSV100314113; called by muse, mutect2
- WWP2 | c.1416T>C p.F472= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as COSV100598656; called by muse, mutect2, varscan2
- ZNF479 | c.1521T>C p.S507= | Silent (SNP) | VAF 14/348 reads (4%) | called by muse, mutect2
- ZNF511 | c.447A>G p.E149= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV100756842; called by muse, mutect2, varscan2
- ZSCAN2 | c.432G>C p.G144= | Silent (SNP) | VAF 137/309 reads (44%) | catalogued as COSV57571822; called by muse, mutect2, varscan2
- ZSCAN5B | c.363T>C p.N121= | Silent (SNP) | VAF 24/249 reads (10%) | catalogued as COSV62838333; called by muse, mutect2, varscan2
- AC005863.1 | n.328T>A | RNA (SNP) | VAF 31/119 reads (26%) | called by muse, mutect2, varscan2
- AC074085.2 | n.228T>C | RNA (SNP) | VAF 26/116 reads (22%) | called by muse, mutect2, varscan2
- EI24P4 | n.1041A>G | RNA (SNP) | VAF 33/581 reads (6%) | called by muse, mutect2
- MRPL11 | c.473+260C>G | Intron (SNP) | VAF 49/253 reads (19%) | catalogued as COSV100207802; called by muse, mutect2, varscan2
- SNORD116-16 | n.52A>G | RNA (SNP) | VAF 154/733 reads (21%) | called by muse, mutect2, varscan2
- TMEM196 | c.*21G>T | 3'UTR (SNP) | VAF 12/107 reads (11%) | called by muse, mutect2, varscan2
